Somatic mutation profile of tumor specimen TCGA-VQ-A8PQ-01A (aliquot TCGA-VQ-A8PQ-01A-11D-A410-08) from TCGA case TCGA-VQ-A8PQ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 50.2 years (18,318 days).
Specimen TCGA-VQ-A8PQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1162e4be-e31a-43dc-98ce-60f67d3ebecd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PQ-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PQ-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab09cd80-d57f-4e0b-b732-59b89fa46c6b

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1H | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100672916; called by muse, mutect2
- FBXO21 | c.1756T>C p.F586L (on ENST00000330622 / NM_033624.3; = p.F579L on NM_015002.3) | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100401772; called by muse, mutect2
- GRIN2A | c.2549C>T p.T850M | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.984); catalogued as rs1060503230, COSV58025417; ClinVar: uncertain significance; called by muse, mutect2
- MAP3K1 | c.3619C>T p.Q1207* | Nonsense Mutation (SNP) | VAF 5/70 reads (7%) | catalogued as COSV68125937; called by muse, mutect2
- ZC3H12A | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs1261191683, COSV100897726; called by muse, mutect2
- KY | c.1911C>T p.V637= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs750617998, COSV101414999; called by muse, mutect2
- PCDHB15 | c.1902C>T p.D634= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV99178991; called by muse, mutect2
- ZNF429 | c.1683A>G p.G561= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100641938; called by muse, mutect2, varscan2
